MMRF case MMRF_2698 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/feef7024-8f1e-4f90-b7c6-5c32897a94d9

Demographics
Sex at birth: male; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.0 years (18,616 days); ISS stage: III; Days to last known disease status: 196 days; Days to last follow up: 196 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -15, day 196.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Beta 2 Microglobulin 13.5 µg/mL.
- Platelets 367 ×10⁹/L.
- Creatinine 211 µmol/L.
- M Protein 0.92 g/dL.
- Hemoglobin 6.14 mmol/L.
- Absolute Neutrophil 13.9 ×10⁹/L.
- Albumin 29 g/L.
- Lactate Dehydrogenase 7.43 µkat/L.
- Serum Free Immunoglobulin Light Chain, Kappa 17.8 mg/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL.
- Calcium 2.32 mmol/L.

Other clinical attributes
- Day -15: Weight: 80 kg; Height: 170 cm.

Biospecimens (2 samples)
- Sample MMRF_2698_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -15 days.
- Sample MMRF_2698_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -15 days.
